Somatic mutation profile of tumor specimen TARGET-20-PARPZP-09A (aliquot TARGET-20-PARPZP-09A-01D) from TARGET case TARGET-20-PARPZP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (566 days).
Specimen TARGET-20-PARPZP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faa68c50-7c12-4fee-9761-3ff3d4169609.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPZP-14A (Bone Marrow Normal), aliquot TARGET-20-PARPZP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26b14150-20a2-4cab-a56f-d96be95f5181

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 29/141 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53134349; called by muse, mutect2
- TDRD6 | c.2978C>T p.T993M | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369734344, COSV60176312; called by muse, mutect2
